Gene-level copy-number profile of tumor specimen TCGA-77-8136-01A from TCGA case TCGA-77-8136, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.5 years (27,193 days).
Specimen TCGA-77-8136-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c26496ed-1574-40fb-9d64-7b5327855504.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8136-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/61cc7996-822d-4e50-bc9a-2e3e477ba569

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 26,082; copy number 2: 31,185; copy number 3: 2,036; copy number 4: 483; copy number 5: 2; copy number 6: 5; copy number 23: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8136-01A-11D-2243-01): tumor purity 0.34, ploidy 1.61, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:25,377,263–27,218,404, 28 genes, copy number 5–23: ANAPC4, AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4, AC024132.2, AC024132.1.

Autosomal genes at a single copy (total copy number 1): 24,182. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
